Gene-level copy-number profile of tumor specimen TCGA-85-8288-01A from TCGA case TCGA-85-8288, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.2 years (25,629 days).
Specimen TCGA-85-8288-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3a434e48-8e3e-4644-8c39-bd820e8a2867.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8288-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3986fb47-e28a-4908-89df-4d60d9aa8383

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 19,546; copy number 2: 37,476; copy number 3: 2,789; copy number 4: 4; copy number 7: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8288-01A-11D-2292-01): tumor purity 0.61, ploidy 1.74, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,289,817–127,482,139, 1 gene, copy number 7 (within-gene range 3–7): CASC8.
- chr8:127,322,183–127,420,066, 2 genes, copy number 7: POU5F1B, CCAT2.

Autosomal genes at a single copy (total copy number 1): 17,125. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
